Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-A4BK, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-A4BK-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3
adenocarcinoma, NOS 8140/3
Site: pancreas, head c25.0

fw
7/26/12

Sex: Male
D.O.B.:
MRN #:
Ref Phys:

SPECIMEN INFORMATION

Collected:
Received:
Reported:

Accession #:
Acct / Reg #:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Celliac lymph node, excision including frozen section examination:

Metastatic adenocarcinoma.

Tumor replaces a 2.5 cm maximum lymph node and extends outside the lymph node capsule.

Permanent sections confirm the frozen section impression.

B. Gallbladder, cholecystectomy:

Chronic cholecystitis.

C. Pancreas, pancreatic duct, margin, including frozen section examination:

Negative for malignancy.

Chronic pancreatitis.

Permanent sections confirm the frozen section impression.

D. Pancreatic margin, biopsy including frozen section examination:

Microscopic focus of adenocarcinoma identified in a background of chronic pancreatitis.

E. Doudenum and head of pancreas, excision including frozen section examination:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.

2. Histologic grade: Focally poorly differentiated.

3. Tumor site: Head of pancreas.

4. Tumor size: 4.7 x 4.5 x 4.2 cm.

5. Microscopic tumor extension:

Tumor involves the head of the pancreas and extends into the soft tissue surrounding the portal vein as well as the common bile duct.

6. Lymphovascular space invasion: Yes.

7. Perineural invasion: Yes.

Surgical Margin Status:

1. Tumor involves the portal vein and the tissue surrounding the common bile duct by frozen section, permanent sections confirm the frozen section impression. Permanent sections also demonstrate the radial margin of the pancreatic resection to be involved by tumor.

Lymph Node Status:

1. Total number of lymph nodes received: 4 lymph nodes including specimen A above identified.

Lymph nodes demonstrating adenocarcinoma two (2/4).

2. Largest involved node measures 2.5 cm.

Other:

1. Other significant findings: Chronic pancreatitis.

2. pTNM stage: pT3, N1.

[page 2 of 2]
SPECIMEN INFORMATION

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: year old Caucasian male, cancer head of pancreas.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Celiac lymph node - FS.
- B. Gallbladder.
- C. Pancreatic duct margin - FS.
- D. Pancreatic margin - FS.
- E. Duodenum and head of pancreas - FS.

SPECIMEN DATA

GROSS DESCRIPTION:

A. Container A is labeled celiac lymph node, #1. Received for frozen section and subsequently placed in formalin, is a 2.5 x 1.5 x 1.5 cm. firm, tan-white lymph node with attached fatty tissue. A portion of the lymph node is submitted for frozen section. The frozen section remnant is re-submitted for permanent in cassette A1 labeled

Representative sections of the remaining lymph node are submitted in cassettes A2-A4 labeled

B. Container B is labeled gallbladder. Received in formalin, is an 8.4 x 4.2 x 3.7 cm. distended gallbladder. The serosa is smooth, slightly dusky, gray-tan. The lumen contains viscous green bile; there are no calculi within the gallbladder, cystic duct, or in the container. The gallbladder mucosa is diffusely green, velvety with a marked amount of cholesterosis and the wall is up to 0.3 cm. thick.

Representative sections are submitted in cassette B1 labeled

C. Container C is labeled pancreatic duct margin. Received for frozen section and subsequently placed in formalin, is a 0.7 x 0.6 x 0.5 cm. portion of yellow-tan tissue. The specimen is submitted for frozen section. The frozen section remnant is re-submitted for permanent in cassette C1 labeled

D. Container D is labeled pancreatic margin. Received for frozen section and subsequently placed in formalin, is a 1.8 cm. in greatest dimensions portion of tan-white soft tissue. The specimen is inked and submitted for frozen section. The frozen section remnant is re-submitted for permanent in cassette D1 labeled

E. Container E is labeled duodenum and head of pancreas. Received in formalin is a Whipple resection consisting of 28.5 cm. long by 4.6 cm. diameter portion of duodenum and an 8.0 x 5.7 x 4.0 cm. head of pancreas. The soft tissue margins near the pancreatic head are inked black. On section, the pancreatic parenchyma gives rise to an ill-defined, 4.7 x 4.5 x 4.2 cm. indurated, focally cystic, tan-white tumor. Tumor extends to the anterior and superior inked soft tissue. Tumor does not grossly involve the ampulla; however, proximal to the ampulla, tumor extends into the serosa of the small bowel. Examination of the minimal amount of fat surrounding the pancreas reveals two, up to 1.0 cm. in greatest dimensions smooth tan-white lymph nodes.

Representative sections are submitted for Genomic studies in three cassettes labeled

Representative sections are submitted for frozen section. The frozen section remnants are re-submitted for permanent in cassettes E1-E4 labeled

Representative sections of the remaining specimen are submitted in cassettes labeled as follows: E5—representative of distal small bowel resection margin; E6-E7 bisected ampulla; E8-E10 pancreatic tumor to anterior soft tissue; E11-E12 representative pancreatic tumor to superior soft tissue; E13—representative posterior soft tissue; E14—representative uninvolved pancreatic parenchyma; E15-E16 tumor to small bowel proximal to ampulla; E17—representative uninvolved small bowel; E18—one sectioned lymph node in toto; E19—one bisected lymph node.

POST-OPERATIVE CONSULTATION:

A. FROZEN SECTION DIAGNOSIS: Metastatic adenocarcinoma per

C. FROZEN SECTION DIAGNOSIS: Negative

D. FROZEN SECTION DIAGNOSIS: Atypical, favor reactive per

E. FROZEN SECTION DIAGNOSIS: E1. Duodenum - negative. E2. Uncinate - negative. E3. portal vein - negative. E4. common bile duct - mucosa - negative, soft tissue - positive all per

Diagnostic Discrepancy		X
HP/NA Discrepancy		X
Reviewed Initials:	8/3/12	

8/3/12

Source: NCI Genomic Data Commons file ec08bbd5-b1b3-415d-a96b-8bc01cc32d84 (TCGA-HZ-A4BK.553B5959-0DB1-4546-A723-55A31E21D403.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).